Somatic mutation profile of tumor specimen 0DRXEH from CCDI case PBCGLF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 17.4 years (6,359 days).
Specimen 0DRXEH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 526ef6e6-8709-439c-8259-9b2545dae589.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRXEN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5ada042-03fa-473e-a979-915c9b8c3dab

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 3, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 160/497 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACADSB | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 166/389 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755077502; called by muse, mutect2, varscan2
- NRXN3 | c.2011G>A p.G671S (on ENST00000335750 / NM_001330195.2; = p.G298S on NM_004796.6) | Missense Mutation (SNP) | VAF 173/508 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs149057434; called by muse, mutect2, varscan2
- PCDHB15 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.686); catalogued as rs17844634, COSV50931745, COSV51003525; called by muse, mutect2, varscan2
- RYR2 | c.10700G>A p.R3567H | Missense Mutation (SNP) | VAF 131/415 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs577371071, COSV63712133, COSV63724982; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCUBE2 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 91/287 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs991815964, COSV58545464; called by muse, mutect2, varscan2
- SUMF2 | c.226G>A p.A76T (on ENST00000652303; = p.A57T on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 169/407 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); catalogued as rs775006852; called by muse, mutect2, varscan2
- AUTS2 | c.754_757dup p.V253Gfs*9 | Frame Shift Ins (INS) | VAF 197/606 reads (33%) | called by mutect2, varscan2
- NCKAP5L | c.1565G>A p.S522N | Missense Mutation (SNP) | VAF 95/159 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NLGN3 | c.1234A>C p.K412Q (on ENST00000358741 / NM_181303.2; = p.K392Q on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- SALL4 | c.1803A>G p.R601= | Silent (SNP) | VAF 121/319 reads (38%) | called by muse, mutect2, varscan2
- SLC22A15 | c.1095G>A p.R365= | Silent (SNP) | VAF 161/436 reads (37%) | catalogued as rs750366800, COSV101047612; called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 8/93 reads (9%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 6/81 reads (7%) | called by mutect2, varscan2
- NSD3 | c.2612-45G>A | Intron (SNP) | VAF 6/36 reads (17%) | called by mutect2, varscan2
